CPTAC case C3L-01237 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8f4be0c-5d75-4c8f-a67b-6d7302c9c372

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 57.4 years (20,956 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 20 days; Days to last follow up: 20 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 9; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 20.

Other clinical attributes
- Weight: 54 kg; Height: 176 cm; BMI: 17.43.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 6; Cigarettes per day: 40; Tobacco smoking onset year: 1977; Tobacco smoking quit year: 1980; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 3.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01237-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 20 days; Initial weight: 290 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01237-24: Section location: Floor of Mouth; Percent tumor nuclei: 80; Percent necrosis: 7.
- Sample C3L-01237-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 20 days; Initial weight: 150 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01237-14: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 20 days; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01237-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 20 days; Method of sample procurement: Blood Draw.
